Surgical pathology report (de-identified scan), TCGA case TCGA-58-A46J, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Thoraxklinik at University Hospital Heidelberg, specimen TCGA-58-A46J-01A (Primary Tumor).

Pathology Report-Summary:

Material:

lung, left: 20.0 x 18.0 x 11.0 cm

tumor in lower lobe: 9.0 x 7.0 x 6.5 cm

Diagnosis:

Squamous Cell Carcinoma, (NOS)

Infiltration of pleura visceralis

pT2, pN1 (3/57), pMx, G3

ICD-O-3

Carcinoma, squamous
cell, NOS 8070/3

Site: lung, lower lobe

9-5-12
RD

C34.3

Pathologist:

Reviewed by (initials):	RJM	

hw
8/21/12

Source: NCI Genomic Data Commons file 4ea05ec7-f1f0-4c30-8de1-ded34094e7c4 (TCGA-58-A46J.18E403FA-639F-4E53-820B-0A756A039C73.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).